Somatic mutation profile of tumor specimen 0DT9NM from CCDI case PBCJCC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Central neurocytoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 16.1 years (5,894 days).
Specimen 0DT9NM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d79582df-fd60-4def-85e1-9a34ba02891d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT9N9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2d768a1-6688-42ab-83ef-51d47a576c07

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ2 | c.693G>T p.E231D | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs797044938, CM162117; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TSC2 | c.879_880del p.G294Sfs*43 | Frame Shift Del (DEL) | VAF 156/442 reads (35%) | catalogued as rs137854364; called by pindel, varscan2
- CRTC3 | c.211A>T p.S71C | Missense Mutation (SNP) | VAF 36/487 reads (7%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.838); called by muse, mutect2
